Surgical pathology report (de-identified scan), TCGA case TCGA-XR-A8TD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XR-A8TD-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular
clear cell type 8174/3
Site: Liver C22.0
9/29/14

Nature of material: Liver

Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received two vials identified as follows:

-Lymph nodes of the hepatic hilum: containing fibro-adipose tissue where four nodular and fibro-elastic fragments were dissected, measuring the largest 4.5 x 3.5 x 0.9 cm and the smallest 1.7 x 0.5 x 0.3 cm.

-Liver: liver segment weighing 2878.0 grams and measuring 21.0 cm in craniocaudal direction, 21.0 cm in side axle and 11.0 cm anteroposteriorly. The outer surface is smooth and brown with bloody area measuring 14.0 x 9.0 cm and nodular brownish lesion with 3.5 cm x 3.0 cm. To the cuts it is note a nodular, withish and soft lesion, measuring 19.5 x 19.0 x 10.0 cm. The gallbladder measures 9.0 x 2.0 cm with smooth and brown-gray serous and greenish mucous.

MICROSCOPY

Expendable description.

DIAGNOSTIC

Product of hepatic trisegmentectomy: *Per TSS, clear cell = 90%.*

-Hepatocellular carcinoma with clear cell pattern, grade III Edmonsson & Steiner, with extensive areas of necrosis, measuring 19.5 x 19 cm in major axis.

-Presence of infiltration of Glisson capsule.

-Vascular elements, lymph nodes of the hepatic hilum, gallbladder and resection margins free of neoplasia.

-Staging: pt3, pno.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

- ISSUER

Source: NCI Genomic Data Commons file 11fdfb2a-227d-4353-a32c-654dd488bbf2 (TCGA-XR-A8TD.DA6BFBB1-CD64-4996-8D5C-73600EBDFE34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).